Surgical pathology report (de-identified scan), TCGA case TCGA-19-A6J4, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-A6J4-01A (Primary Tumor).

[page 1 of 2]
Gender: M

DOB: [REDACTED]

Age: [REDACTED]

Phone: [REDACTED]

Address: [REDACTED]

Result Detail

Pathology Result: [REDACTED]

Specimen Collected Date: [REDACTED]

Specimen Received Date: [REDACTED]

Order Number: [REDACTED]

Ordering Provider: [REDACTED]

Medical Record Number: [REDACTED]

Facility: [REDACTED]

Status: [REDACTED]

Accession #: [REDACTED]

Pathologist: [REDACTED]

Date of Procedure: [REDACTED]

Date Received: [REDACTED]

Date Reported: [REDACTED]

Submitting Physician: [REDACTED]

Location: [REDACTED]

Addendum Present

FINAL DIAGNOSIS

A. LEFT BRAIN TUMOR, EXCISION:

--GLIOBLASTOMA (WHO GRADE IV), SEE NOTE.

Note: The tumor has a prominent component of large cells with granular cytoplasm and large PAS positive inclusions (granular cell differentiation).

Note

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's).

ASR's

have not been cleared or approved by the U.S. Food and Drug Administration.

These assays were developed and their performance characteristics determined by [REDACTED]. The

FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing. The assays were performed with appropriate positive and negative controls which stained appropriately.

Electronically Signed

Out By [REDACTED]

Addendum/Procedures:

Addendum Date Ordered: [REDACTED]

Status: Signed Out

Date Complete: [REDACTED]

Date Reported: [REDACTED]

Addendum Diagnosis

Immunohistochemistry with antibody directed against CD68 is reactive with large granular tumor cells.

Electronically Signed Out By [REDACTED]

Clinical History:

Left brain tumor

ICD-O-3
Glioblastoma multiforme
9440/3
Sate Q4CF
Brain NOS 071.9
path
Brain, supratentorial NOS
071.0
JW 7/24/13

[page 2 of 2]
Specimens Submitted As:

A:LEFT BRAIN TUMOR

Gross Description:

Received fresh, labeled with the patient's name, number, and "tumor", are

multiple light tan irregular soft tissue fragments measuring 2.5 x 2.2 x 0.5 cm in aggregate. Submitted in toto in two cassettes.

Primary/Tumor Site Discrepancy		///

Source: NCI Genomic Data Commons file 08ae9609-a559-49c1-a135-396530cd5fc9 (TCGA-19-A6J4.39E56F35-C780-4461-8FDF-D0754CF38351.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).